Somatic mutation profile of tumor specimen MP2PRT-PAUPZC-TMP1-A (aliquot MP2PRT-PAUPZC-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUPZC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,455 days).
Specimen MP2PRT-PAUPZC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 457e2f2e-bed3-49b2-a38b-da875329fe9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUPZC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUPZC-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f900abd-7c28-4159-a39f-cb423b98ae30

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYHR1 | c.82A>G p.S28G | Missense Mutation (SNP) | VAF 131/462 reads (28%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as rs781267578; called by muse, mutect2, varscan2
- PRRC2C | c.5441C>G p.S1814* (on ENST00000367742; = p.S1812* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 162/632 reads (26%) | catalogued as COSV100145319, COSV58903667; called by muse, mutect2, varscan2
- TTC26 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 77/301 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs557708154; called by muse, mutect2, varscan2
- LAMA3 | c.7076A>C p.Q2359P (on ENST00000313654 / NM_198129.4; = p.Q750P on NM_000227.6) | Missense Mutation (SNP) | VAF 136/458 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RIMS1 | c.2154G>T p.K718N | Missense Mutation (SNP) | VAF 96/290 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ZMYM2 | c.3647T>C p.L1216P | Missense Mutation (SNP) | VAF 89/400 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1orf115 | c.420C>T p.F140= | Silent (SNP) | VAF 82/286 reads (29%) | catalogued as rs762749655, COSV54273872; called by muse, mutect2, varscan2
- CACHD1 | c.2739G>A p.T913= | Silent (SNP) | VAF 60/259 reads (23%) | catalogued as rs1202602620, COSV51553609; called by muse, mutect2, varscan2
- GSR | c.16C>A p.R6= | Silent (SNP) | VAF 24/580 reads (4%) | called by muse, mutect2
- SPC25 | c.540G>A p.R180= | Silent (SNP) | VAF 28/153 reads (18%) | called by muse, mutect2, varscan2
